FM case AD6333 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/7fd2c982-582f-4d78-a6b0-bd6c9a61946f

Male, 75.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
